Somatic mutation profile of tumor specimen TCGA-24-1845-01A (aliquot TCGA-24-1845-01A-01W-0639-09) from TCGA case TCGA-24-1845, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 42.7 years (15,599 days).
Specimen TCGA-24-1845-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ab470bb7-50c5-4c6e-bb25-8d5beb39fc69.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-1845-10A (Blood Derived Normal), aliquot TCGA-24-1845-10A-01W-0639-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/762d7f76-6c30-41b7-8bd5-b1098341744e

The open-access MAF lists 181 somatic variants for this specimen: 144 protein-altering or splice-affecting, 31 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 119, Silent 31, Frame Shift Del 8, Nonsense Mutation 5, Intron 4, In Frame Del 3, Frame Shift Ins 3, Splice Site 2, Splice Region 2, Nonstop Mutation 2, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.159G>A p.W53* | Nonsense Mutation (SNP) | VAF 223/249 reads (90%) | hotspot (GDC flag); catalogued as rs1064794618, COSV52751414, COSV53223969, COSV53499187; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACOT8 | c.950G>T p.S317I | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.694); catalogued as COSV99467604; called by muse, mutect2
- ADAM30 | c.475G>A p.V159I | Missense Mutation (SNP) | VAF 30/153 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.206); catalogued as COSV65560571; called by muse, mutect2, varscan2
- ADAMTS15 | c.1927C>A p.P643T | Missense Mutation (SNP) | VAF 98/1377 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as rs1398624837, COSV100143431; called by muse, mutect2
- AHCYL1 | c.294C>A p.N98K | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.553); catalogued as COSV100779599; called by muse, mutect2
- AHR | c.110A>C p.K37T | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769051991, COSV54122177; called by muse, mutect2, varscan2
- AL645922.1 | c.581A>G p.Y194C | Missense Mutation (SNP) | VAF 74/349 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs758382884, COSV54959657; called by muse, mutect2, varscan2
- ALDH1L1 | c.2578G>T p.V860F | Missense Mutation (SNP) | VAF 51/71 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV56411784; called by muse, mutect2, varscan2
- ALDH1L1 | c.319C>A p.P107T | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs921639395, COSV99856958; called by muse, mutect2
- AMIGO1 | c.1408G>C p.G470R | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV100880974, COSV63990282; called by muse, mutect2, varscan2
- ANK3 | c.3140T>G p.V1047G (on ENST00000280772 / NM_001320874.2; = p.V181G on NM_001149.3) | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55048251; called by muse, mutect2, varscan2
- ANKRD30A | c.2703A>C p.Q901H (on ENST00000611781; = p.Q845H on NM_052997.2) | Missense Mutation (SNP) | VAF 88/232 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); catalogued as COSV64606031; called by muse, mutect2, varscan2
- ASPA | c.196G>T p.D66Y | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52151777; called by muse, mutect2, varscan2
- ASTN2 | c.1852A>C p.T618P (on ENST00000313400 / NM_001365069.1; = p.T567P on NM_014010.5) | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as COSV57758681; called by muse, mutect2, varscan2
- ATP6V0A1 | c.2134G>A p.D712N (on ENST00000343619 / NM_001378531.1; = p.D706N on NM_005177.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/299 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.036); catalogued as COSV99231127; called by muse, varscan2
- BEND2 | c.63C>A p.N21K | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.263); catalogued as COSV66215268; called by muse, varscan2
- C17orf58 | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 68/110 reads (62%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.853); catalogued as rs111513651, COSV100558715, COSV57816763; called by muse, varscan2
- C1orf146 | c.17A>T p.K6I | Missense Mutation (SNP) | VAF 69/190 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.405); catalogued as COSV64880169; called by muse, mutect2, varscan2
- CAMTA1 | c.586C>A p.L196I | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV57886515; called by muse, mutect2, varscan2
- CELSR2 | c.4783G>A p.A1595T | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs200048357, COSV54768267; called by muse, mutect2, varscan2
- CIT | c.5211C>G p.I1737M | Missense Mutation (SNP) | VAF 64/175 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV55862794; called by muse, mutect2, varscan2
- CLEC4C | c.347C>A p.A116D | Missense Mutation (SNP) | VAF 40/748 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100665473; called by muse, mutect2
- COL5A1 | c.4726C>G p.L1576V | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.396); catalogued as COSV65666366; called by muse, mutect2, varscan2
- COL6A6 | c.4820C>A p.P1607H | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.924); catalogued as rs764725422, COSV62019748; called by muse, mutect2, varscan2
- CORO2A | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); catalogued as COSV59662368; called by muse, mutect2, varscan2
- CSE1L | c.744G>C p.L248F | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.092); catalogued as COSV53700645; called by muse, mutect2, varscan2
- CSMD1 | c.9680T>A p.I3227K (on ENST00000520002; = p.I3226K on NM_033225.6) | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.937); catalogued as COSV100149129; called by muse, mutect2, varscan2
- CTNNA3 | c.539A>T p.E180V | Missense Mutation (SNP) | VAF 54/155 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.273); catalogued as COSV57717707; called by muse, mutect2, varscan2
- DCX | c.668G>A p.G223E | Missense Mutation (SNP) | VAF 129/718 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as CM010025, CM980533, COSV100576745, COSV57566845; called by muse, mutect2, varscan2
- DENND5B | c.3646C>T p.R1216C | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs1488658943, COSV60900651, COSV60902248; called by muse, mutect2, varscan2
- DFFB | c.744G>T p.E248D | Missense Mutation (SNP) | VAF 29/46 reads (63%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV58860481; called by muse, mutect2, varscan2
- DHX9 | c.2941A>G p.N981D | Missense Mutation (SNP) | VAF 48/253 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.216); catalogued as COSV62358601; called by muse, mutect2, varscan2
- DOCK7 | c.185A>T p.D62V | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as COSV51998438; called by muse, mutect2, varscan2
- DYNC1I1 | c.1738G>T p.A580S | Missense Mutation (SNP) | VAF 7/130 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.802); catalogued as COSV61468840; called by muse, mutect2
- EIF3L | c.1369C>G p.L457V | Missense Mutation (SNP) | VAF 53/320 reads (17%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.544); catalogued as COSV67739451; called by muse, mutect2, varscan2
- EP400 | c.8035G>A p.V2679I | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV100201365, COSV57789577; called by muse, mutect2
- ERICH3 | c.46C>T p.L16F | Missense Mutation (SNP) | VAF 83/473 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100444666, COSV58599479; called by muse, mutect2, varscan2
- FAM104B | c.223G>T p.A75S | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT tolerated (0.49); PolyPhen benign (0.058); catalogued as COSV100146100; called by muse, mutect2
- FAM214A | c.908G>A p.G303D | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as rs757550997, COSV55922683; called by muse, mutect2, varscan2
- FBXL19 | c.1021C>G p.L341V | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.019); catalogued as COSV57941176; called by muse, mutect2, varscan2
- FCRLA | c.451_458del p.F151Hfs*51 (on ENST00000367959; = p.F128Hfs*51 on NM_032738.4) | Frame Shift Del (DEL) | VAF 23/127 reads (18%) | catalogued as COSV52684720; called by mutect2, pindel*, varscan2
- FIP1L1 | c.454C>G p.L152V | Missense Mutation (SNP) | VAF 42/167 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.082); catalogued as COSV60994462; called by muse, mutect2, varscan2
- FMO4 | c.213C>A p.D71E | Missense Mutation (SNP) | VAF 30/382 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100882070, COSV100882182; called by muse, mutect2
- FOXP2 | c.1283G>C p.S428T | Missense Mutation (SNP) | VAF 44/668 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.827); catalogued as COSV100646818; called by muse, mutect2
- FRMD7 | c.1148C>T p.S383F | Missense Mutation (SNP) | VAF 24/416 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100049060; called by muse, mutect2
- GBF1 | c.767C>T p.T256I | Missense Mutation (SNP) | VAF 26/441 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.166); catalogued as COSV100890521; called by muse, mutect2
- GRIA3 | c.1450G>T p.D484Y | Missense Mutation (SNP) | VAF 60/473 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52051718, COSV52072690; called by muse, mutect2, varscan2
- HEG1 | c.3487C>A p.L1163I | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.028); catalogued as COSV60760090; called by muse, mutect2, varscan2
- HEPHL1 | c.31T>A p.F11I | Missense Mutation (SNP) | VAF 119/329 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV59890071; called by muse, mutect2, varscan2
- HRH2 | c.13G>T p.G5C | Missense Mutation (SNP) | VAF 102/354 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.343); catalogued as COSV51573284; called by muse, mutect2, varscan2
- IFI44L | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 37/152 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1391612787, COSV60726873; called by muse, mutect2, varscan2
- IGHMBP2 | c.1765G>A p.G589S | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54820682; called by muse, mutect2, varscan2
- IGSF1 | c.3681C>G p.S1227R | Missense Mutation (SNP) | VAF 204/1082 reads (19%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.993); catalogued as COSV63836567; called by muse, mutect2, varscan2
- IL20RB | c.670G>T p.V224L | Missense Mutation (SNP) | VAF 31/456 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); catalogued as COSV100291100; called by muse, mutect2
- KCNA4 | c.826G>T p.V276L | Missense Mutation (SNP) | VAF 71/264 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.04); catalogued as COSV60251099; called by muse, mutect2, varscan2
- KLHL24 | c.784C>A p.P262T | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV99664963; called by muse, mutect2
- LAMP5 | c.743T>A p.V248D | Missense Mutation (SNP) | VAF 28/167 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV55715424; called by muse, mutect2, varscan2
- LDLRAD4 | c.129C>G p.D43E | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63334764; called by muse, mutect2, varscan2
- LRP12 | c.824A>G p.Y275C | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52626739; called by muse, mutect2, varscan2
- LRRK1 | c.2175C>A p.N725K | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52604442; called by muse, mutect2, varscan2
- LTBR | c.440A>T p.D147V | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.024); catalogued as COSV57438409; called by muse, mutect2, varscan2
- MOGAT3 | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.265); catalogued as COSV99777188; called by muse, mutect2
- MPHOSPH8 | c.1933-9_1962del p.X645_splice | Splice Site (DEL) | VAF 20/60 reads (33%) | catalogued as COSV64054707; called by mutect2, pindel, varscan2
- MSL2 | c.1350G>C p.K450N | Missense Mutation (SNP) | VAF 58/217 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV53860577, COSV53866410; called by muse, mutect2, varscan2
- MTMR4 | c.1577G>A p.R526Q | Missense Mutation (SNP) | VAF 78/556 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs758600036, COSV60199652; called by muse, mutect2, varscan2
- MUC17 | c.9181C>T p.P3061S | Missense Mutation (SNP) | VAF 86/319 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs370113176, COSV60282436, COSV60304484; called by mutect2, varscan2
- MYO9A | c.5465T>G p.F1822C | Missense Mutation (SNP) | VAF 51/84 reads (61%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV61848561; called by muse, mutect2, varscan2
- MYOCD | c.2000C>A p.A667D | Missense Mutation (SNP) | VAF 61/66 reads (92%) | SIFT tolerated (0.43); PolyPhen benign (0.075); catalogued as COSV58499061, COSV58503214; called by muse, mutect2, varscan2
- MYT1L | c.1904A>G p.E635G | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67712322, COSV67726740; called by muse, mutect2, varscan2
- MYT1L | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.337); catalogued as COSV67710494; called by muse, mutect2, varscan2
- NFE2L2 | c.1785del p.S597Vfs*15 | Frame Shift Del (DEL) | VAF 58/378 reads (15%) | catalogued as COSV101229291; called by pindel, varscan2
- NIM1K | c.847A>T p.I283F | Missense Mutation (SNP) | VAF 45/206 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58140136; called by muse, mutect2, varscan2
- NIP7 | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.433); catalogued as COSV54741850; called by muse, mutect2, varscan2
- NR2C1 | c.1094A>G p.E365G | Missense Mutation (SNP) | VAF 11/229 reads (5%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.984); catalogued as COSV100280516; called by muse, mutect2
- NTRK3 | c.911C>T p.P304L | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58113395; called by muse, mutect2, varscan2
- NUP133 | c.2846C>A p.A949D | Missense Mutation (SNP) | VAF 48/218 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54569014; called by muse, varscan2
- OASL | c.1303C>T p.Q435* | Nonsense Mutation (SNP) | VAF 132/323 reads (41%) | catalogued as COSV56566497; called by muse, mutect2, varscan2
- OR10C1 | c.118G>C p.V40L (on ENST00000622521; = p.V38L on NM_013941.3) | Missense Mutation (SNP) | VAF 108/706 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV65822372, COSV65823334; called by muse, mutect2, varscan2
- PCNX3 | c.319C>A p.Q107K | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as COSV58419607; called by muse, mutect2
- PHF3 | c.1022C>A p.S341Y | Missense Mutation (SNP) | VAF 28/198 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.365); catalogued as COSV50314445; called by muse, mutect2
- PODN | c.1901G>A p.G634D (on ENST00000395871; = p.G586D on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/125 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.32); catalogued as COSV100439648; called by muse, mutect2
- POLD2 | c.1217A>G p.N406S | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.502); catalogued as rs1312319738, COSV56256003; called by muse, mutect2, varscan2
- PTPRB | c.935G>C p.R312T | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.297); catalogued as COSV54235761, COSV99719488; called by muse, mutect2, varscan2
- RASGRF1 | c.544C>T p.L182F | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.717); catalogued as COSV69177252; called by muse, mutect2, varscan2
- RC3H2 | c.961C>T p.L321= | Splice Region (SNP) | VAF 72/130 reads (55%) | catalogued as COSV59010856; called by muse, mutect2, varscan2
- RHEB | c.159A>T p.E53D | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.013); catalogued as COSV51262602; called by muse, mutect2, varscan2
- RNF112 | c.189G>C p.R63S | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.991); catalogued as COSV71978770; called by muse, mutect2, varscan2
- RXRB | c.1515G>T p.E505D | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.963); catalogued as COSV100554131; called by muse, mutect2
- S100A11 | c.230T>A p.F77Y | Missense Mutation (SNP) | VAF 62/117 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54975559; called by muse, mutect2, varscan2
- SAMD9L | c.2676G>A p.M892I | Missense Mutation (SNP) | VAF 61/487 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as COSV59080185; called by muse, mutect2, varscan2
- SCN1A | c.410C>A p.T137N | Missense Mutation (SNP) | VAF 10/236 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV100320761; called by muse, mutect2
- SCRN2 | c.1004C>G p.T335S | Missense Mutation (SNP) | VAF 23/28 reads (82%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV51635168; called by muse, mutect2, varscan2
- SELENOV | c.953A>T p.H318L | Missense Mutation (SNP) | VAF 95/352 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59063440; called by muse, mutect2, varscan2
- SERPIND1 | c.529G>C p.V177L | Missense Mutation (SNP) | VAF 118/434 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.027); catalogued as COSV53137685; called by muse, varscan2
- SGPP1 | c.1051C>T p.P351S | Missense Mutation (SNP) | VAF 54/98 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55974756; called by muse, mutect2, varscan2
- SHROOM3 | c.1933G>A p.E645K | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.165); catalogued as COSV99934540; called by muse, mutect2
- SLC16A10 | c.1066G>T p.V356L | Missense Mutation (SNP) | VAF 73/175 reads (42%) | SIFT tolerated (0.58); PolyPhen benign (0.015); catalogued as COSV64353770; called by muse, mutect2, varscan2
- SLC1A6 | c.463C>A p.P155T | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99693832; called by muse, mutect2
- SLC5A6 | c.208C>A p.P70T | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100143332, COSV100143451; called by muse, mutect2
- SLITRK4 | c.1820T>C p.I607T | Missense Mutation (SNP) | VAF 268/436 reads (61%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV62022540; called by muse, mutect2, varscan2
- SNX27 | c.1239G>T p.M413I | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV100919058; called by muse, mutect2, varscan2
- SNX27 | c.1239+1G>T p.X413_splice | Splice Site (SNP) | VAF 15/93 reads (16%) | catalogued as COSV100919059; called by muse, mutect2, varscan2
- SNX29 | c.1013A>G p.Q338R | Missense Mutation (SNP) | VAF 73/153 reads (48%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.163); catalogued as COSV100030207, COSV60053397; called by muse, mutect2, varscan2
- SORBS2 | c.2056A>T p.R686* | Nonsense Mutation (SNP) | VAF 33/42 reads (79%) | catalogued as COSV52993805; called by muse, mutect2, varscan2
- SP140 | c.1432T>A p.C478S | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV59447329; called by muse, mutect2, varscan2
- SPIRE1 | c.1777C>A p.L593I (on ENST00000409402 / NM_001128626.2; = p.L579I on NM_020148.3) | Missense Mutation (SNP) | VAF 73/116 reads (63%) | SIFT tolerated (0.58); PolyPhen benign (0.111); catalogued as COSV59153423; called by muse, mutect2, varscan2
- SPTBN2 | c.4879G>T p.V1627L | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV59448615; called by muse, mutect2, varscan2
- SUPV3L1 | c.460C>T p.H154Y | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs1262479457, COSV100669719; called by muse, mutect2
- SYNE4 | c.734C>A p.T245K | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV53324081; called by muse, mutect2, varscan2
- SYNPO2L | c.2728dup p.R910Pfs*8 (on ENST00000394810 / NM_001114133.3; = p.R686Pfs*8 on NM_024875.5) | Frame Shift Ins (INS) | VAF 5/32 reads (16%) | catalogued as rs764821235; called by mutect2, pindel, varscan2
- SZT2 | c.8150A>C p.K2717T (on ENST00000634258 / NM_001365999.1; = p.K2660T on NM_015284.4) | Missense Mutation (SNP) | VAF 42/307 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.52); catalogued as COSV65168027; called by muse, mutect2, varscan2
- TESK1 | c.243A>T p.Q81H | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.344); catalogued as COSV52410446; called by muse, mutect2, varscan2
- TIMMDC1 | c.239C>T p.T80M | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs113067251, COSV51786189; called by muse, mutect2, varscan2
- TLN2 | c.6790C>G p.P2264A | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV60886918; called by muse, mutect2, varscan2
- TMEM132B | c.1133G>T p.G378V | Missense Mutation (SNP) | VAF 11/267 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as COSV100169908; called by muse, mutect2
- TMEM61 | c.151G>T p.A51S | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.889); catalogued as COSV64873400; called by muse, mutect2, varscan2
- TMEM98 | c.186A>C p.L62F | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.787); catalogued as COSV55582367; called by muse, mutect2, varscan2
- TNXB | c.3971C>A p.S1324Y (on ENST00000647633; = p.S1077Y on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100926398; called by muse, mutect2
- TRIM46 | c.1759G>A p.V587M | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV100104453; called by muse, mutect2
- TRIP10 | c.1569C>A p.D523E (on ENST00000313244 / NM_001288962.2; = p.D467E on NM_004240.4) | Missense Mutation (SNP) | VAF 253/291 reads (87%) | SIFT tolerated (1); PolyPhen probably damaging (0.97); catalogued as COSV55585029; called by muse, mutect2, varscan2
- TRPA1 | c.2061C>T p.N687= | Splice Region (SNP) | VAF 16/140 reads (11%) | catalogued as rs541532801, COSV51557007; called by muse, mutect2, varscan2
- TRRAP | c.4143G>T p.Q1381H | Missense Mutation (SNP) | VAF 252/1586 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as COSV62840808; called by muse, varscan2
- TTC13 | c.2567G>C p.C856S | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV64168005, COSV64170652; called by muse, mutect2, varscan2
- UBAP2L | c.2122A>G p.T708A | Missense Mutation (SNP) | VAF 97/272 reads (36%) | SIFT tolerated (0.82); PolyPhen benign (0.014); catalogued as rs765139848, COSV55169254; called by muse, mutect2, varscan2
- UBXN6 | c.133del p.R45Afs*16 | Frame Shift Del (DEL) | VAF 9/37 reads (24%) | catalogued as COSV56678015; called by mutect2, pindel, varscan2
- UGGT1 | c.1768G>A p.V590I | Missense Mutation (SNP) | VAF 57/135 reads (42%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV52133150; called by muse, mutect2, varscan2
- ZFYVE27 | c.759dup p.K254Efs*26 | Frame Shift Ins (INS) | VAF 4/31 reads (13%) | catalogued as rs1295639405; called by pindel, varscan2
- ZKSCAN7 | c.1271C>T p.S424F | Missense Mutation (SNP) | VAF 18/211 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV99837641; called by muse, mutect2
- ZNF160 | c.1362G>C p.K454N | Missense Mutation (SNP) | VAF 135/304 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV61999096; called by muse, mutect2, varscan2
- ZNF236 | c.1076A>T p.Q359L | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); catalogued as COSV53483917; called by muse, mutect2, varscan2
- ZSCAN20 | c.682G>T p.E228* | Nonsense Mutation (SNP) | VAF 57/99 reads (58%) | catalogued as COSV63681775; called by muse, mutect2, varscan2
- ACO1 | c.580G>T p.G194* | Nonsense Mutation (SNP) | VAF 15/455 reads (3%) | called by muse, mutect2
- CALB2 | c.803_*10del | Nonstop Mutation (DEL) | VAF 182/1097 reads (17%) | called by mutect2, pindel, varscan2
- CR1 | c.5294G>C p.S1765T | Missense Mutation (SNP) | VAF 19/241 reads (8%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.992); called by muse, mutect2
- KIAA0319 | c.2838_2855del p.W946_N951del | In Frame Del (DEL) | VAF 13/124 reads (10%) | called by mutect2, pindel
- MROH9 | c.1035_1062del p.I346Rfs*9 | Frame Shift Del (DEL) | VAF 51/153 reads (33%) | called by mutect2, pindel, varscan2
- MUC16 | c.7242_7257del p.V2415Qfs*47 | Frame Shift Del (DEL) | VAF 30/66 reads (45%) | called by mutect2, pindel, varscan2
- NCOA3 | c.3391_3415del p.Q1131* | Frame Shift Del (DEL) | VAF 31/245 reads (13%) | called by mutect2, pindel
- PTPRO | c.3072_3095del p.M1024_Q1031del (on ENST00000281171 / NM_030667.3; = p.M996_Q1003del on NM_002848.4) | In Frame Del (DEL) | VAF 26/202 reads (13%) | called by mutect2, pindel
- SETMAR | c.561del p.K187Nfs*8 | Frame Shift Del (DEL) | VAF 28/63 reads (44%) | called by mutect2, pindel, varscan2
- STT3B | c.980_1003del p.V327_Y334del | In Frame Del (DEL) | VAF 40/169 reads (24%) | called by pindel, varscan2
- STT3B | c.1058dup p.F354Lfs*14 | Frame Shift Ins (INS) | VAF 39/200 reads (20%) | called by pindel, varscan2*
- TSPAN18 | c.741_*13del | Nonstop Mutation (DEL) | VAF 10/30 reads (33%) | called by mutect2, pindel, varscan2
- ZFHX3 | c.2813_2837del p.N938Sfs*20 | Frame Shift Del (DEL) | VAF 7/83 reads (8%) | called by mutect2, pindel
- ABTB1 | c.804C>T p.F268= (on ENST00000232744 / NM_172027.3; = p.F126= on NM_032548.3) | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV99229489; called by muse, mutect2
- ANTXR2 | c.939A>T p.T313= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV56313553; called by muse, mutect2, varscan2
- ARMT1 | c.1191C>T p.L397= | Silent (SNP) | VAF 15/75 reads (20%) | called by muse, mutect2
- ATP7B | c.912T>A p.S304= | Silent (SNP) | VAF 6/86 reads (7%) | catalogued as COSV99666534; called by muse, mutect2
- CACNA1F | c.2788C>T p.L930= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as rs782798933, COSV100544978; called by muse, mutect2
- FARSA | c.1410C>G p.G470= | Silent (SNP) | VAF 30/146 reads (21%) | catalogued as COSV53365868; called by muse, mutect2, varscan2
- FGA | c.2268C>A p.S756= | Silent (SNP) | VAF 66/136 reads (49%) | catalogued as COSV57393895; called by muse, mutect2, varscan2
- FMO4 | c.1143A>G p.T381= | Silent (SNP) | VAF 84/244 reads (34%) | catalogued as COSV63000728; called by muse, mutect2, varscan2
- FXR2 | c.282G>A p.V94= | Silent (SNP) | VAF 22/24 reads (92%) | catalogued as rs1296639145, COSV51517985; called by muse, mutect2, varscan2
- GCM2 | c.699T>A p.P233= | Silent (SNP) | VAF 81/236 reads (34%) | catalogued as COSV65275224; called by muse, mutect2, varscan2
- KCNF1 | c.936C>T p.T312= | Silent (SNP) | VAF 3/51 reads (6%) | catalogued as rs1423621957, COSV99705744; called by muse, mutect2
- KLK3 | c.450C>A p.T150= | Silent (SNP) | VAF 37/70 reads (53%) | catalogued as COSV58099303; called by muse, mutect2, varscan2
- LHB | c.279G>A p.P93= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as rs377599735, COSV55484007; called by muse, mutect2, varscan2
- LRRC58 | c.564G>A p.L188= | Silent (SNP) | VAF 34/118 reads (29%) | catalogued as COSV55229691; called by muse, mutect2, varscan2
- MMP27 | c.696C>T p.A232= | Silent (SNP) | VAF 33/193 reads (17%) | catalogued as COSV52780033; called by muse, mutect2, varscan2
- NPC1L1 | c.3261G>A p.Q1087= | Silent (SNP) | VAF 141/330 reads (43%) | catalogued as COSV99212296; called by muse, varscan2
- OBSL1 | c.1407G>A p.P469= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs761576373, COSV54714593, COSV54724589; called by muse, mutect2, varscan2
- PDE11A | c.1548T>C p.P516= | Silent (SNP) | VAF 37/231 reads (16%) | catalogued as COSV53689011; called by muse, mutect2, varscan2
- PLIN4 | c.1020C>A p.T340= (on ENST00000301286; = p.T355= on NM_001367868.2) | Silent (SNP) | VAF 16/26 reads (62%) | catalogued as rs111683150, COSV56688031; called by muse, mutect2
- PLXNA4 | c.5493A>T p.A1831= | Silent (SNP) | VAF 27/163 reads (17%) | catalogued as COSV58110886; called by muse, varscan2
- PRKG2 | c.1806G>T p.G602= | Silent (SNP) | VAF 46/143 reads (32%) | catalogued as COSV52320800; called by muse, mutect2, varscan2
- PTCHD3 | c.1311G>A p.G437= | Silent (SNP) | VAF 67/161 reads (42%) | catalogued as COSV71256370; called by muse, mutect2, varscan2
- PTCHD3 | c.1225C>A p.R409= | Silent (SNP) | VAF 98/134 reads (73%) | catalogued as COSV71256373; called by muse, mutect2, varscan2
- PTPRE | c.747C>G p.P249= | Silent (SNP) | VAF 16/216 reads (7%) | called by muse, mutect2
- SH3PXD2B | c.1761G>T p.L587= | Silent (SNP) | VAF 24/86 reads (28%) | catalogued as COSV61125310; called by muse, mutect2, varscan2
- SLC17A2 | c.399C>A p.T133= | Silent (SNP) | VAF 387/643 reads (60%) | catalogued as COSV55350808, COSV55353068; called by muse, mutect2, varscan2
- SLC1A6 | c.1488G>T p.V496= | Silent (SNP) | VAF 254/317 reads (80%) | catalogued as COSV55668707; called by muse, mutect2, varscan2
- SLC4A1 | c.2214C>A p.L738= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as COSV52258867; called by muse, mutect2, varscan2
- SLC6A9 | c.957G>A p.T319= (on ENST00000360584 / NM_201649.4; = p.T265= on NM_006934.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as rs1426686992, COSV62210072; called by muse, mutect2, varscan2
- SPPL2C | c.777G>A p.V259= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV100234070; called by muse, mutect2
- TENM1 | c.1818C>A p.T606= | Silent (SNP) | VAF 17/542 reads (3%) | catalogued as COSV64449272; called by muse, mutect2
- FAM183BP | n.999G>A | RNA (SNP) | VAF 7/70 reads (10%) | called by muse, mutect2, varscan2
- GRIA2 | c.2406+467del | Intron (DEL) | VAF 10/75 reads (13%) | called by mutect2, pindel, varscan2
- KIF16B | c.3498+2812G>T | Intron (SNP) | VAF 27/86 reads (31%) | catalogued as COSV61702517; called by muse, mutect2, varscan2
- NCAM1 | c.2131+2590T>C | Intron (SNP) | VAF 14/88 reads (16%) | catalogued as COSV57512251; called by muse, mutect2, varscan2
- TOMM20 | c.121+697C>A | Intron (SNP) | VAF 63/267 reads (24%) | catalogued as COSV64012454; called by muse, mutect2, varscan2
- Y_RNA | chr7:75515796 C>T | 5'Flank (SNP) | VAF 42/235 reads (18%) | called by muse, mutect2, varscan2
